Gene-level copy-number profile of tumor specimen MP2PRT-PAVPXP-TMP1-A from MP2PRT case MP2PRT-PAVPXP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (674 days).
Specimen MP2PRT-PAVPXP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 98365ab2-63ce-4a8f-bc88-bbe38f909223.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVPXP-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/b8d03b8e-c03f-4a5d-adbc-4ca373810c03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 3,009; copy number 2: 55,499; copy number 3: 282.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 16 genes: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4.
- chr14:22,066,016–22,552,156, 96 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
